Gene-level copy-number profile of tumor specimen C3N-02788-03 from CPTAC case C3N-02788, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 64.7 years (23,634 days).
Specimen C3N-02788-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 332ad9f4-20ac-4227-abe6-7f96862f8ca0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02788-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/c841f2d3-e1c4-4cfd-af0d-590561869625

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 20; copy number 1: 9,301; copy number 2: 45,710; copy number 3: 3,124; copy number 4: 474; copy number 5: 17; copy number 8: 56; copy number 9: 40; copy number 10: 18; copy number 11: 100; copy number 12: 31; copy number 17: 23.

Homozygous deletions (total copy number 0; autosomes only): 20 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,409,117–21,441,316, 4 genes: IFNA8, AL353732.2, IFNWP2, IFNA1.
- chr9:21,455,484–21,482,313, 2 genes (within-gene range 0–1): IFNWP19, IFNE.
- chr10:87,607,985–88,259,372, 14 genes: AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 285 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:167,441,789–184,135,238, 276 genes, copy number 5–17 (within-gene range 1–17) (broad region; genes not listed).
- chr3:184,230,429–184,249,548, 3 genes, copy number 11 (within-gene range 1–11): VWA5B2, MIR1224, ALG3.
- chr3:184,249,695–184,293,031, 2 genes, copy number 11 (within-gene range 1–11): EEF1AKMT4-ECE2, CAMK2N2.
- chr3:184,314,495–184,361,650, 4 genes, copy number 11 (within-gene range 1–11): EIF4G1, SNORD66, FAM131A, CLCN2.

Autosomal genes at a single copy (total copy number 1): 6,979. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
